Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A17Y, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A17Y-06A (Metastatic).

12/9/10 *lw*

1CB-0-3

Melanoma, NOS 8720/3
Site Code: Back, NOS C44.5

years Male

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:UUID: C5289022-0B12-4759-9B2E-431E001366C4

**HISTOPATHOLOGY REPORT****CLINICAL DETAILS**

Recent melanoma right back. 1. Mid right back with previous R/T failed. 2. Tumour lateral right back.

MACROSCOPIC DESCRIPTION

Two specimens were received.

1. "R BACK". The specimen consists of an unorientated ellipse of skin measuring 23 x 8mm with an underlying piece of fibrofatty tissue measuring 12mm in depth. Resection margins inked blue. No significant abnormality noted on the skin surface. The specimen is transversely sectioned from one end to the other. All embedded serially in blocks A - B.

2. "R LATERAL BACK". The specimen consists of an ellipse of skin measuring 68 x 30 x 23mm with a central linear scar measuring 28mm. The specimen was already ? incised on deep surface prior to receipt. Resection margin and inside of the ? incised area inked blue and deep surface of the skin adjacent to the incisions is inked black. Specimen was taken for tumour banking. Specimen is serially and transversely sectioned from one end to the other. Sectioning of the specimen shows a tumour in subcutaneous tissue measuring 30 x 22 x 15mm in maximum extent. The tumour lies about 2mm from deep margin.

A - C. Representative sections of the tumour with closest deep margin.

Photos are taken.

MICROSCOPIC REPORT**1. "R BACK"**

The sections show recurrent melanoma associated with a scar. The lesion is about 9mm across and extends to a depth of 13mm in deep dermis and subcutis. The lesion is poorly circumscribed but appears clear of margins by about 0.2mm. The lesion is composed of large, markedly pleomorphic cells with an epithelioid appearance. Mitoses are frequent.

2. "R LATERAL BACK"

The sections show a central nodule of metastatic melanoma about 15mm across and portion of a deeper lesion 7mm across involving the deep margin. The cells are epithelioid in appearance but smaller and less pleomorphic than in specimen 1. Immunoperoxidase staining is positive for S100, HMB45 and Melan-A but negative for cytokeratin, confirming melanoma.

SUMMARY

1. SKIN OF BACK - RECURRENT MELANOMA

2. SKIN OF BACK - METASTATIC MELANOMA

REPORTED BY: Dr

Local/Synchronous Findings		X

CR clinical bx for Rad Tx

Source: NCI Genomic Data Commons file 5945964a-3142-425f-a39b-b4d1318fdd29 (TCGA-EE-A17Y.C52B9022-0B12-4759-9B2E-431E001366C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).